Gene-level copy-number profile of tumor specimen TCGA-55-5899-01A from TCGA case TCGA-55-5899, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung.
Specimen TCGA-55-5899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.db7bc967-6d2a-49d9-81e8-d83261fe3a9b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-5899-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ee93c08e-425c-4508-9c58-e34fc0e83d32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 100; copy number 1: 1,389; copy number 2: 25,741; copy number 3: 20,110; copy number 4: 10,859; copy number 5: 314; copy number 6: 1,130; copy number 7: 8; copy number 11: 3; copy number 13: 10; copy number 14: 23; copy number 15: 7; copy number 16: 51; copy number 17: 23; copy number 18: 17; copy number 22: 9; copy number 24: 4; copy number 39: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-5899-01A-11D-1624-01): tumor purity 0.67, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,512,115–32,334,354, 99 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,618 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,601,061–88,950,928, 2 genes, copy number 6: NDUFA5P5, ICE2P2.
- chr4:150,209,706–157,962,924, 141 genes, copy number 14–39 (within-gene range 3–39) (broad region; genes not listed).
- chr4:157,945,817–157,946,642, 1 gene, copy number 17: AC017037.4.
- chr5:45,890,216–45,895,970, 1 gene, copy number 16: AC122694.1.
- chr6:12,290,361–17,034,396, 64 genes, copy number 5 (broad region; genes not listed).
- chr6:55,106,460–63,319,983, 58 genes, copy number 6: HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN.
- chr7:70,972–57,777,521, 1,070 genes, copy number 6 (broad region; genes not listed).
- chr8:37,734,761–47,960,178, 198 genes, copy number 5 (broad region; genes not listed).
- chr9:32,455,302–33,577,014, 40 genes, copy number 5: DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2, AQP3, AL356218.1, NOL6, MIR6851, SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7.
- chr9:38,540,569–38,577,207, 1 gene, copy number 7 (within-gene range 2–7): FAM95C.
- chr9:38,566,260–38,720,428, 7 genes, copy number 7: SNX18P3, ANKRD18A, FAM201A, YWHABP1, AL591543.1, RNU6-765P, FAM240B.
- chr13:29,764,371–29,888,405, 4 genes, copy number 13–16 (within-gene range 3–16): UBL3, Metazoa_SRP, TIMM8BP1, LINC00297.
- chr13:52,842,889–52,848,641, 1 gene, copy number 13: PCDH8.
- chr13:53,193,667–53,202,753, 2 genes, copy number 15: AL136359.1, PCDH8P1.
- chr13:83,877,205–83,907,781, 3 genes, copy number 11: SLITRK1, AL355481.1, VENTXP2.
- chr13:94,698,725–94,803,430, 6 genes, copy number 13 (within-gene range 2–13): LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112.
- chr13:101,778,884–101,802,488, 2 genes, copy number 13: RNU1-24P, HMGB3P7.
- chr13:108,207,439–108,308,484, 5 genes, copy number 15: LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39.
- chr17:52,390,515–54,365,634, 12 genes, copy number 5 (within-gene range 4–5): LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1.

Autosomal genes at a single copy (total copy number 1): 794. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
